Surgical pathology report (de-identified scan), TCGA case TCGA-X9-A973, project TCGA-SARC (Sarcoma), tissue source site University of California, Davis, specimen TCGA-X9-A973-01A (Primary Tumor).

[page 1 of 5]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT: [REDACTED]

ACCT #: [REDACTED]

REG DR:

AGE/SX: M

DOB:

STATUS:

SPEC #: [REDACTED]

RECV:

STATUS:

REQ #: [REDACTED]

SPEC:

SUBM DR:

ORD LOC:

TYPE: SURG PATH

ASSN TO:

PT AGE AT RECV:

ENTERED:

ENT BY:

OTHR DR:

DEPT:

RECV BY:

LAST RPTD:

LAST ACT:

TAT HRS:

SLIDES:

ORDERED: G&M Level 3, G&M Level 6

DELETED: NO CHARGE -

ORD SITE:

TRANSIT SITE:

RCV SITE:

AT SITE:

PERFORM SITE:

RPT AUDIT:

ICD O.3
Sarcoma, pleomorphic cell,
undifferentiated (8802/3)
Code to highest 8805/3
Site: Retroperitoneum 0480
Path Pelvic, rgt tissue 049.5
YD 5/19/14

STATUS HX:

ACTIVITY DATE TIME TYPE

1

RECORD STATUS USER
SENT

Continued on next page ...

[page 2 of 5]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 2

SPEC #: [REDACTED] PATIENT: [REDACTED] ACCT #: [REDACTED]

2	SENT
3	SENT
4	SENT

CODES: TY6000 - Pelvis
T11340|T11341 - Ilium
Edited by:

PROCEDURES: G&M Level 3
G&M Level 6
Edited by:

TISSUES:
A. Bone, ilium - RIGHT EXTERNAL ILIAC TISSUE
B. Pelvis - RADICAL RESECTION - RIGHT PELVIC SARCOMA
Edited by:

CLINICAL INFORMATION

Suspected Diagnosis: Sarcoma
Clinical Information: Unlisted
Collected by:
Other/Special Requests: [REDACTED]
Edited by:

GROSS DESCRIPTION

A. Received in formalin, designated as "right external iliac tissue," are two segments of pink and yellow soft tissue aggregating to 3.5 x 1.3 x 0.8 cm. Each tissue segment is bisected and entirely submitted in cassettes A1-A2.

B. Received without fixative, designated as "radical resection right pelvic sarcoma," is a 15 x 12 x 9.5 cm soft tissue mass. The outer surface is partially covered by fatty soft tissue and skeletal muscle. The outer surface is inked blue. The specimen is sectioned revealing an ill-defined 14.7 x 9 x 9 cm tumor with fleshy pink-tan cut surfaces. Central areas of necrosis and cystic regions are present on cut surface. Tissue is collected for cytogenetic analysis. Tissue is forwarded for
Additionally, representative sections are submitted in cassettes B1-B10.

Edited by:

Continued on next page ...

[page 3 of 5]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 3

SPEC #: [REDACTED] PATIENT: [REDACTED] ACCT #: [REDACTED]

ICD 9 DATA CAPTURE

ICD-9 171.6 Modifier

Discrepancy CODER

Entry Date
Edited by:

Review by

Review Date

MICROSCOPIC DESCRIPTION

Slides were examined microscopically and the diagnosis for each specimen incorporates the pathologist's interpretation.

Edited by:

DIAGNOSIS

A. SOFT TISSUE, RIGHT EXTERNAL ILIUM (BIOPSY):

- BENIGN FIBROADIPOSE TISSUE.
- NO MALIGNANCY SEEN.

B. SOFT TISSUE, RIGHT PELVIS (RADICAL RESECTION):

- PLEOMORPHIC UNDIFFERENTIATED SARCOMA (MFH), HIGH GRADE, SEE SYNOPTIC REPORT.

SYNOPTIC REPORT:

Procedure:

Radical resection

Tumor Site:

Specify (if known): RIGHT PELVIS

Tumor Size:

Greatest dimension: 14.7 cm

Macroscopic Extent of Tumor:

Deep

Histologic Type (World Health Organization [WHO] classification of soft tissue tumors):

Specify: PLEOMORPHIC UNDIFFERENTIATED SARCOMA, HIGH GRADE

Mitotic Rate:

Specify: > 5 /10 high-power fields (HPF)

Necrosis:

Present

Extent: 20%

Histologic Grade (French Federation of Cancer Centers Sarcoma Group [FNCLCC]) (Note D):

Grade 3

Margins:

Margins negative for sarcoma

Distance of sarcoma from closest margin: 0.1 cm

Specify margin: CAPSULAR

Lymph-Vascular Invasion:

Continued on next page ...

[page 4 of 5]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 4

SPEC #: [REDACTED] PATIENT: [REDACTED] ACCT #: [REDACTED]

DIAGNOSIS

(Continued)

Not identified

Pathologic Staging (pTNM):

Primary Tumor: (pT)

pT2b: Tumor more than 5 cm in greatest dimension, deep tumor

Regional Lymph Nodes: (pN)

pNX: Regional lymph nodes cannot be assessed

Distant Metastasis (pM)

Not applicable

Review/Concur: This case was signed out by
this case and agrees with the above interpretation.

has also reviewed

Edited by:

QA CODES/COMPLIANCE

Q. A. 1

Edited by:

RESIDENT ASSIGNED

NONE

Edited by:

SUPPLEMENTARY REPORT

Addendum #1

Entered:

Cytogenetics ([REDACTED]) results performed and interpreted at [REDACTED] are as follows:

RESULTS

STAINING TECHNIQUES: NONE

CELLS COUNTED: 0

CELLS ANALYZED: 0

CELLS KARYOTYPED: 0

RESULTS: SPECIMEN DID NOT GROW

INTERPRETATION

This specimen did not grow.

Reason for no growth: No metaphases were seen.

The Class I analyte-specific reagents used in some of the Immunohistochemistry tests

Continued on next page ...

[page 5 of 5]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 5

SPEC #:

PATIENT:

ACCT #:

SUPPLEMENTARY REPORT

(Continued)

reported were developed and their performance characteristics determined by . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Addendum Final:

Edited by:

Final:

SIGN OUT AUDIT	DATE	TYPE	ADD/PARC SEC	ACTION	ENTERED BY	DATE	TIME
				ADD			
				ADD			

*** End of Report ***

Criteria	1/24/14	Yes	No
Dual/Synchronous Primary	Noted		

Source: NCI Genomic Data Commons file e7f2c1cb-1942-4919-9e4e-74d83276a78d (TCGA-X9-A973.F46AED6F-1C25-4CEB-ADA2-7BBD1273B9B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).